Somatic mutation profile of tumor specimen TCGA-BW-A5NQ-01A (aliquot TCGA-BW-A5NQ-01A-11D-A27I-10) from TCGA case TCGA-BW-A5NQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.9 years (23,353 days).
Specimen TCGA-BW-A5NQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f7dd5b4-0bb1-43de-9429-9308aae117b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BW-A5NQ-10A (Blood Derived Normal), aliquot TCGA-BW-A5NQ-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2607a071-f21d-443b-a056-f96072a1844e

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 28, Nonsense Mutation 5, 3'UTR 4, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, 5'UTR 1, In Frame Del 1, In Frame Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 88/238 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3214A>G p.I1072V | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as rs1334293891, COSV67982992; called by muse, mutect2, varscan2
- APOA4 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV63360307; called by muse, mutect2, varscan2
- ARHGEF7 | c.1747G>A p.G583R (on ENST00000375741 / NM_001113511.2; = p.G405R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV54541707; called by muse, mutect2, varscan2
- ATP13A4 | c.2435C>A p.P812Q | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.808); catalogued as rs1443793301, COSV61318653; called by muse, mutect2, varscan2
- B3GALT1 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59908461; called by mutect2, varscan2
- BDP1 | c.6659A>T p.D2220V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV62430635; called by muse, mutect2, varscan2
- BVES | c.448T>A p.C150S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV58947269; called by muse, mutect2, varscan2
- CACNA2D4 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54948000; called by muse, mutect2, varscan2
- CC2D1A | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58782470; called by muse, mutect2, varscan2
- CCHCR1 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV66183406; called by muse, mutect2, varscan2
- CCNE1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52904046; called by muse, mutect2, varscan2
- CDH12 | c.1422T>A p.N474K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66397489; called by muse, mutect2, varscan2
- CDH18 | c.315T>A p.D105E | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56914382; called by muse, mutect2, varscan2
- CEACAM5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV55751665; called by muse, mutect2, varscan2
- COL6A3 | c.7066G>T p.G2356* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as CM1310908, COSV55085936, COSV55086152, COSV55102703; called by muse, mutect2, varscan2
- CPA4 | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55982886; called by muse, mutect2, varscan2
- CSMD3 | c.10958A>C p.K3653T (on ENST00000297405 / NM_001363185.1; = p.K3484T on NM_052900.3) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52149724; called by muse, mutect2, varscan2
- CTNND2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV58879012; called by muse, mutect2, varscan2
- DMXL2 | c.7781T>G p.L2594R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV51844046; called by muse, mutect2, varscan2
- DPYD | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594664; called by muse, mutect2, varscan2
- DYRK1B | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs774158060, COSV59913282; called by muse, mutect2, varscan2
- ELAPOR2 | c.2588G>A p.C863Y (on ENST00000450689 / NM_001142749.3; = p.C696Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553991387, COSV51885660; called by muse, mutect2, varscan2
- ELAVL1 | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs768294547, COSV60966192; called by muse, mutect2, varscan2
- EML5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs763457989, COSV61344205; called by muse, mutect2, varscan2
- ENDOD1 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53589203; called by muse, mutect2, varscan2
- ERG | c.46T>G p.L16V | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729864; called by muse, mutect2, varscan2
- FBN3 | c.1742T>C p.I581T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV54457860; called by muse, mutect2, varscan2
- FIG4 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV57786761; called by muse, varscan2
- FLG | c.5330C>G p.S1777C | Missense Mutation (SNP) | VAF 91/398 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64240084, COSV64241923; called by muse, mutect2, varscan2
- FLNB | c.4292T>A p.L1431Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM070931, COSV55876110; called by muse, mutect2, varscan2
- GNAI1 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63522384; called by muse, mutect2, varscan2
- HIVEP2 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV50008550; called by muse, mutect2, varscan2
- HMCN1 | c.14665G>C p.G4889R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54891434; called by muse, mutect2, varscan2
- HSPA1L | c.764T>G p.I255S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV65148976; called by muse, mutect2, varscan2
- ITGAV | c.2846C>A p.S949Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV53711222; called by muse, mutect2, varscan2
- KY | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); catalogued as COSV71016986; called by muse, mutect2, varscan2
- MED13 | c.5251C>A p.P1751T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV67262920; called by muse, mutect2, varscan2
- MKRN3 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV58809430; called by muse, mutect2, varscan2
- MROH2B | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV68182815; called by muse, mutect2, varscan2
- MUC16 | c.38183A>C p.E12728A | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as rs1284096131, COSV67458596; called by muse, mutect2, varscan2
- NBEA | c.3782T>G p.I1261S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV59774888; called by muse, mutect2, varscan2
- NDRG2 | c.623C>A p.S208Y (on ENST00000298687 / NM_001354570.1; = p.S194Y on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100069187, COSV53872034; called by muse, mutect2, varscan2
- NEXMIF | c.3842G>T p.G1281V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV50026572; called by muse, mutect2, varscan2
- NLRP3 | c.1947del p.K650Rfs*70 | Frame Shift Del (DEL) | VAF 83/232 reads (36%) | catalogued as COSV60229924; called by mutect2, pindel, varscan2
- OR2L5 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs746325958, COSV62364485; called by muse, mutect2, varscan2
- OR5W2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV60615500; called by muse, mutect2, varscan2
- PEAK1 | c.2405A>G p.D802G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56933459; called by muse, mutect2, varscan2
- PIGS | c.560T>A p.V187D | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV52024097; called by muse, mutect2, varscan2
- PLPPR5 | c.949T>C p.F317L (on ENST00000263177 / NM_001037317.2; = p.F312L on NM_001010861.3) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV54171523; called by muse, mutect2, varscan2
- PROSER3 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56553094; called by muse, mutect2, varscan2
- RAB39A | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57694707; called by muse, mutect2, varscan2
- RGL1 | c.2012G>A p.S671N (on ENST00000360851 / NM_001297672.2; = p.S706N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV58982898; called by muse, mutect2, varscan2
- RILP | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200277401; called by muse, mutect2, varscan2
- RTN4 | c.2921T>C p.V974A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.035); catalogued as COSV58266392; called by muse, mutect2, varscan2
- SESTD1 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101468144, COSV70567330; called by muse, mutect2, varscan2
- SMARCC2 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV57216752; called by muse, mutect2
- SMIM2 | c.24T>G p.D8E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.631); catalogued as rs1229376312; called by muse, mutect2, varscan2
- SNRNP200 | c.2276C>T p.T759I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs765309591, COSV60488999; called by muse, mutect2, varscan2
- SORCS2 | c.2620C>T p.Q874* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs756446383, COSV61167113; called by muse, mutect2, varscan2
- SPATA48 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV50423978; called by muse, mutect2, varscan2
- SYNE2 | c.11560A>C p.I3854L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV59946552; called by muse, mutect2, varscan2
- TAOK3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV66825363; called by muse, mutect2, varscan2
- TAPT1 | c.1508T>A p.I503N | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV58823123; called by muse, mutect2, varscan2
- TG | c.2864A>T p.E955V | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV55072084, COSV55098634; called by muse, mutect2, varscan2
- TIGD2 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs768437030, COSV57647530; called by muse, mutect2, varscan2
- TPO | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100219337, COSV61099393; called by muse, mutect2
- TRIM46 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55278560; called by muse, mutect2, varscan2
- TXN2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53397431; called by muse, mutect2, varscan2
- VEPH1 | c.687dup p.Q230Tfs*22 | Frame Shift Ins (INS) | VAF 36/125 reads (29%) | catalogued as rs1240884977; called by mutect2, pindel, varscan2
- ZNF714 | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52510979; called by muse, mutect2, varscan2
- ZSWIM2 | c.1231A>G p.R411G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV54574758; called by muse, mutect2, varscan2
- AFF4 | c.777del p.M260Wfs*25 | Frame Shift Del (DEL) | VAF 146/330 reads (44%) | called by mutect2, varscan2
- ARID1A | c.5915_5919dup p.Q1974Tfs*43 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, varscan2
- IGHV1OR21-1 | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2
- LCP2 | c.805dup p.I269Nfs*27 | Frame Shift Ins (INS) | VAF 26/166 reads (16%) | called by mutect2, varscan2
- MAP2K4 | c.676_678dup p.I226dup | In Frame Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- MUC5AC | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- NDRG2 | c.622T>C p.S208P (on ENST00000298687 / NM_001354570.1; = p.S194P on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASGRF1 | c.42_44del p.L15del | In Frame Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TMEM200A | c.48del p.R16Sfs*52 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.66C>A p.I22= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs1305481572, COSV60979152; called by muse, mutect2, varscan2
- CAVIN2 | c.912G>A p.E304= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV58423782; called by muse, mutect2, varscan2
- DTHD1 | c.1854C>T p.V618= (on ENST00000456874; = p.V453= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs1189740433, COSV62628744; called by muse, mutect2, varscan2
- DUSP10 | c.939C>T p.T313= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as COSV60457298; called by muse, mutect2, varscan2
- FAT2 | c.12675C>T p.G4225= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55817431; called by muse, mutect2
- GSAP | c.2241G>T p.L747= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- HECW2 | c.4539A>T p.S1513= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV53655437; called by muse, mutect2, varscan2
- HRH2 | c.498G>A p.K166= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as COSV51573704; called by muse, mutect2
- IGHD | c.681C>T p.S227= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, varscan2
- KCNN2 | c.1089C>T p.D363= (on ENST00000264773; = p.D575= on NM_021614.4) | Silent (SNP) | VAF 57/279 reads (20%) | catalogued as COSV53286727; called by muse, mutect2, varscan2
- KIAA2026 | c.3393T>C p.G1131= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV67354344; called by muse, mutect2, varscan2
- LAMA1 | c.7795T>C p.L2599= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs940238033, COSV67535058; called by muse, mutect2, varscan2
- LOXL2 | c.360C>T p.P120= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs537778489, COSV66691002; called by muse, mutect2, varscan2
- MRGPRX1 | c.894G>T p.A298= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs374955450, COSV57106685; called by muse, mutect2, varscan2
- NELL1 | c.96C>A p.I32= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as COSV54254024; called by muse, mutect2, varscan2
- NLRP14 | c.1104C>G p.V368= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV55065836; called by muse, mutect2, varscan2
- NYAP2 | c.687C>T p.S229= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV56002506; called by muse, mutect2, varscan2
- OR6Y1 | c.924G>A p.K308= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV56929051; called by muse, mutect2, varscan2
- PDS5A | c.2184A>T p.A728= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1391453193, COSV57824570; called by muse, mutect2, varscan2
- PER3 | c.2601A>G p.P867= | Silent (SNP) | VAF 77/196 reads (39%) | catalogued as rs1268148916, COSV62705296; called by muse, mutect2, varscan2
- PLEKHA6 | c.2973G>T p.R991= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV55329432; called by muse, mutect2, varscan2
- PRDM2 | c.495C>A p.S165= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1288605658, COSV99342630; called by muse, mutect2, varscan2
- PTPRB | c.1056A>G p.R352= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV54238244; called by muse, mutect2, varscan2
- RAP2C | c.327C>G p.V109= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV61683294; called by muse, mutect2, varscan2
- SVEP1 | c.720G>A p.E240= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as COSV57033576; called by muse, mutect2, varscan2
- TAF4B | c.621C>T p.V207= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs778101540, COSV52302761; called by muse, mutect2, varscan2
- TBC1D8 | c.1887G>C p.V629= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV65211423; called by muse, mutect2, varscan2
- ZNF839 | c.90C>T p.A30= (on ENST00000558850 / NM_001267827.1; = p.A146= on NM_018335.5) | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1159890435, COSV51756982; called by muse, varscan2
- EDDM3A | c.*321C>T | 3'UTR (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100473430; called by muse, mutect2, varscan2
- KCTD15 | c.693+239G>T | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52289687; called by mutect2, varscan2
- KRT17P1 | n.375C>T | RNA (SNP) | VAF 28/117 reads (24%) | catalogued as rs1363742912; called by muse, mutect2
- MGAT4A | c.404-192A>T | Intron (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99384671; called by muse, mutect2, varscan2
- MTPN | c.*2395C>A | 3'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101262994; called by muse, mutect2, varscan2
- PHB2 | c.*22C>T | 3'UTR (SNP) | VAF 15/45 reads (33%) | catalogued as rs966144550, COSV100017266; called by muse, mutect2, varscan2
- RBP2 | c.-10G>A | 5'UTR (SNP) | VAF 40/109 reads (37%) | catalogued as rs754856421, COSV99218476; called by muse, mutect2, varscan2
- TMEM215 | c.*1673T>G | 3'UTR (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100713241; called by muse, mutect2
